Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3518, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3518-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Ileocolic resectate under inclusion of a moderately differentiated adenocarcinoma of the colorectal type, located in the cecum and of max. 5.5 cm in size, with infiltration of the pericolic fatty tissue. No regional lymph node metastases. Small and large intestinal resection margins tumor-free. Mesenteric resection margin tumor-free. A secondary finding is two submucosal lipomas in the ascending colon.

Tumor stage thus: pT3 pN0 (0/27) pMX; G2, L0, V0, R0.

Source: NCI Genomic Data Commons file ff3d6557-0dbf-49aa-abe9-b8c249b45dc1 (TCGA-AA-3518.DA1E7681-76E1-456F-B8D1-ED08C844C122.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).